Gene-level copy-number profile of tumor specimen TCGA-29-1705-02A from TCGA case TCGA-29-1705, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 48.0 years (17,530 days).
Specimen TCGA-29-1705-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0d6bedbe-ff61-47a2-9ded-c15c88db91c8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1705-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/3f7bcfc4-449a-4c2d-83da-5e939a951eca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 625; copy number 1: 19,600; copy number 2: 30,959; copy number 3: 7,359; copy number 4: 1,279; copy number 5: 352; copy number 6: 1; copy number 7: 86.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:194,488,103–194,488,205, 1 gene: RNU6-983P.
- chr1:212,858,275–212,917,577, 2 genes (within-gene range 0–1): FLVCR1, AC104333.4.
- chr1:237,471,119–237,471,191, 1 gene: MIR4428.
- chr2:64,450,096–64,461,381, 2 genes (within-gene range 0–2): AC008074.1, LGALSL.
- chr5:123,344,890–123,423,592, 1 gene (within-gene range 0–1): CEP120.
- chr6:32,812,763–32,838,822, 2 genes (within-gene range 0–2): HLA-DOB, AL669918.1.
- chr9:21,367,424–30,575,012, 95 genes (within-gene range 0–1) (broad region; genes not listed).
- chr10:132,783,179–132,786,147, 1 gene: NKX6-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 439 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,690,177–94,947,341, 138 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:109,539,711–120,813,359, 94 genes, copy number 5–6 (broad region; genes not listed).
- chr8:121,380,137–127,742,951, 117 genes, copy number 5 (broad region; genes not listed).
- chr8:127,795,962–127,960,695, 4 genes, copy number 5: MIR1204, AC084123.1, TMEM75, MIR1205.
- chr14:105,836,765–106,293,808, 86 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
